Gene-level copy-number profile of specimen HCM-STAN-1277-C55-85B from HCMI case HCM-STAN-1277-C55, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage IIIC1.
Specimen HCM-STAN-1277-C55-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1aa3cc3a-a989-497b-bd16-ea746a98354d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-1277-C55-11B (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,251 have no estimate.
https://portal.gdc.cancer.gov/files/1f437820-22a8-400c-a434-b34495929bf5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 3,875; copy number 2: 29,424; copy number 3: 21,517; copy number 4: 3,175; copy number 5: 232; copy number 6: 25; copy number 7: 97; copy number 8: 9; copy number 9: 4; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,571,481–4,594,016, 1 gene: LINC01646.
- chr6:26,158,146–26,206,038, 12 genes: H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 368 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:240,489,573–240,612,155, 1 gene, copy number 5 (within-gene range 3–5): GREM2.
- chr1:240,549,867–240,590,748, 2 genes, copy number 5: AL358176.2, AL358176.4.
- chr1:240,763,334–241,357,230, 3 genes, copy number 5 (within-gene range 3–5): AL365184.1, THAP12P8, RGS7.
- chr1:240,998,451–241,305,882, 3 genes, copy number 5: AL590682.1, MIR3123, AL592076.1.
- chr2:89,252,211–89,254,015, 2 genes, copy number 6: IGKV3-31, IGKV1-32.
- chr2:191,792,797–191,820,257, 1 gene, copy number 5: AC098872.1.
- chr3:169,902,980–169,966,734, 5 genes, copy number 5 (within-gene range 4–5): KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3.
- chr3:172,630,249–172,831,229, 9 genes, copy number 5–6: NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1.
- chr3:190,830,965–190,832,173, 1 gene, copy number 6: AC092952.1.
- chr4:24,998,847–25,030,946, 1 gene, copy number 5: LGI2.
- chr5:946,315–1,246,189, 10 genes, copy number 5: AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18.
- chr5:1,725,149–1,900,493, 9 genes, copy number 5: AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4.
- chr5:142,325,293–142,761,035, 5 genes, copy number 5–7 (within-gene range 3–7): SPRY4-AS1, RPS12P10, FGF1, AC005592.1, LINC01844.
- chr7:726,699–2,844,308, 56 genes, copy number 5–9 (within-gene range 4–9): DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655, MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1, GNA12, AC006028.1.
- chr7:20,217,577–20,221,700, 1 gene, copy number 6: AC005083.1.
- chr7:30,752,137–30,923,812, 4 genes, copy number 5 (within-gene range 4–5): INMT-MINDY4, MINDY4, AC004691.1, AC004691.2.
- chr8:101,034,868–101,076,407, 1 gene, copy number 5: FLJ42969.
- chr9:128,128,529–128,130,628, 1 gene, copy number 10: PTGES2-AS1.
- chr12:52,079,704–52,601,538, 33 genes, copy number 5 (within-gene range 3–5): SMIM41, OR7E47P, AC078864.1, LINC00592, KRT80, LINC02874, METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A, KRT5, KRT71, KRT74, KRT72.
- chr12:132,277,349–132,280,900, 2 genes, copy number 8 (within-gene range 3–8): AC148477.2, AC148477.5.
- chr14:99,500,190–99,604,207, 1 gene, copy number 5 (within-gene range 3–5): CCDC85C.
- chr14:99,583,017–99,583,118, 1 gene, copy number 5: Y_RNA.
- chr15:71,792,638–71,818,259, 1 gene, copy number 5: NR2E3.
- chr17:16,786,489–16,816,540, 7 genes, copy number 5 (within-gene range 4–5): USP32P1, SRP68P1, AC098850.4, AC098850.1, FAM106C, AC022596.1, NOS2P4.
- chr17:16,829,999–16,832,830, 1 gene, copy number 5: KRT16P2.
- chr17:17,303,335–17,347,663, 1 gene, copy number 5: NT5M.
- chr17:81,244,811–81,835,050, 37 genes, copy number 5–8: SLC38A10, AC027601.3, AC027601.4, LINC00482, TMEM105, AC027601.5, AC110285.3, AC110285.1, AC110285.5, AC110285.2, BAHCC1, AC110285.6, MIR4740, MIR3186, AC110285.4, LINC01971, ACTG1, AC139149.1, FSCN2, FAAP100, NPLOC4, Y_RNA, TSPAN10, PDE6G, OXLD1, CCDC137, ARL16, HGS, MIR6786, AC139530.3, AC139530.1, MRPL12, AC139530.2, SLC25A10, GCGR, MCRIP1, PPP1R27.
- chr20:47,209,214–47,786,616, 12 genes, copy number 7–8: ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1, SULF2, AL354813.1.
- chr20:59,123,381–62,861,822, 78 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:63,005,927–63,537,376, 29 genes, copy number 7: BHLHE23, LINC01749, LINC00029, LINC01056, HAR1B, AL096828.4, HAR1A, AL096828.2, AL096828.1, MIR124-3, YTHDF1, AL096828.3, BIRC7, MIR3196, NKAIN4, FLJ16779, ARFGAP1, MIR4326, COL20A1, RNU6-994P, CHRNA4, AL121827.1, KCNQ2, AL353658.1, KCNQ2-AS1, EEF1A2, AL121829.1, PPDPF, PTK6.
- chr20:63,657,810–64,327,972, 47 genes, copy number 5: RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.
- chr22:24,806,169–24,946,695, 3 genes, copy number 5: SGSM1, AL049759.1, TMEM211.

Autosomal genes at a single copy (total copy number 1): 3,875. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
